Somatic mutation profile of tumor specimen BA2156D (aliquot aq-BA2156D) from BEATAML1.0 case 2017, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.4 years (20,245 days).
Specimen BA2156D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2406d567-2a93-43fd-a04c-157f56ab9196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2796D (Solid Tissue Normal), aliquot aq-BA2796D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20a02209-2c1a-4895-afb5-111decb3e05d

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.912_913insTTG p.K304_Q305insL | In Frame Ins (INS) | VAF 114/285 reads (40%) | catalogued as COSV57196793, COSV57196937, COSV57200730; called by mutect2, pindel, varscan2
- CEBPA | c.242_243insCTTGGTT p.F82Lfs*28 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | catalogued as COSV57195734, COSV57198186; called by mutect2, pindel, varscan2
- CHD9 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); catalogued as COSV68297739; called by muse, mutect2, varscan2
- GATA2 | c.949A>C p.N317H | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62003319; called by muse, mutect2, varscan2
- IMPG1 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100886294; called by muse, mutect2, varscan2
- KIF7 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs367734857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP1 | c.3718C>T p.R1240C | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs908019945; called by muse, mutect2, varscan2
- SMC1A | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 123/144 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as CM096587; called by muse, mutect2, varscan2
- AADACL4 | c.231T>A p.D77E | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DPH2 | c.260+7A>G | Splice Region (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- FAM170A | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KMT2D | c.14857G>T p.A4953S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.118); called by muse, mutect2
- NKRF | c.822dup p.Q275Afs*5 | Frame Shift Ins (INS) | VAF 63/103 reads (61%) | called by mutect2, pindel, varscan2
- ST7 | c.1404C>A p.G468= (on ENST00000265437 / NM_021908.3; = p.G445= on NM_018412.4) | Splice Region (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- TXNDC15 | c.388del p.L130Ffs*41 | Frame Shift Del (DEL) | VAF 50/117 reads (43%) | called by mutect2, pindel, varscan2
- ZBTB4 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- FOXI2 | c.651G>A p.A217= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100511127; called by muse, mutect2, varscan2
- P3R3URF-PIK3R3 | c.180C>T p.T60= | Silent (SNP) | VAF 64/194 reads (33%) | catalogued as rs980322460; called by muse, varscan2
- UMOD | c.1311C>T p.T437= | Silent (SNP) | VAF 65/164 reads (40%) | catalogued as rs748219272, COSV56774511; called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891841 C>T | 5'Flank (SNP) | VAF 109/298 reads (37%) | catalogued as rs746146059; called by muse, mutect2, varscan2
